CCDI case PBCGDN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Oropharynx.
https://portal.gdc.cancer.gov/cases/b3ec5cf2-7165-45a1-b3d7-0e937776c5ad

Demographics
Sex at birth: male; Race: asian.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Posterior wall of oropharynx; Age at diagnosis: 18.6 years (6,811 days).

Biospecimens (3 samples)
- Sample 0DRE0I: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DRE0Q: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DRE0U: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
